Surgical pathology report (de-identified scan), TCGA case TCGA-3U-A98F, project TCGA-MESO (Mesothelioma), tissue source site University of Chicago, specimen TCGA-3U-A98F-01A (Primary Tumor).

[page 1 of 4]
Sample

Gender: Male

DOB:

Race: White

Report Date:

Tissue Procurement Date:

ICD O-3
Mesothelioma, biphasic
malignant 95363
Site @ Pleura No 5 238.4
J10/12/14

Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right chest wall mass; biopsy:

- Skeletal muscle and fibroadipose tissue with reactive changes and acute and chronic inflammation.

B. R4 lymph node; biopsy:

- Two lymph nodes, no tumor.

C. Number 7 lymph node; biopsy:

- Seventeen lymph nodes, no tumor.

D. Pleural peel; resection:

- Malignant biphasic tumor most consistent with biphasic mesothelioma.

Thoracic Mesothelioma Pathologic Parameters

Pleura/Pericardium, Resection

MACROSCOPIC

Specimen Type: Pleural resection

Tumor Site: Right pleura

Tumor Configuration and Size: Diffuse, maximum thickness: 18.5 cm

MICROSCOPIC

Histologic Type: Biphasic mesothelioma (90% sarcomatoid, 10% epithelioid)

Tumor Extension

Into but not through diaphragm

Endothoracic fascia

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Margins: Cannot be assessed

*Pathologic Staging (pTNM): pT3, N0

Primary Tumor (pT): pT3: Tumor (locally advanced but potentially resectable) involves any of the ipsilateral pleural surfaces, with at least 1 of the following: invasion of the endothoracic fascia, invasion into mediastinal fat, solitary completely resectable focus of tumor invading the soft tissues of the chest wall, non-transmural involvement of the pericardium

[page 2 of 4]
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis

*Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pleural mesothelioma of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

This is a biphasic tumor. The majority of the stromal component is highly cellular with spindle-type hyperchromatic cells that frequently overlap with one another. There is focally more fibrotic stroma. The spindle cell component extends into polypoid masses that are covered with single layer of epithelioid cells. The epithelioid cells are cuboidal to columnar with well-defined cell borders and clear-to-eosinophilic cytoplasm. This is not classic for mesothelioma. Therefore the differential diagnosis including synovial sarcoma, solitary fibrous tumor, carcinosarcoma, metastatic renal cell carcinoma and malignant peripheral nerve cell tumor was considered.

Immunohistochemistry (controls appropriate): Epithelioid component and focally the sarcomatoid component are positive for calretinin, WT-1, cytokeratin (CAM 5.2), EMA, CAIX, Bcl2, D2-40, CK5/6. Sarcomatoid component is focally positive for SMA with very weak focal positivity for TLE-1. There is very focal epithelial positivity for MOC31. Tumor is negative for MIC2, Chromogranin, Pax8, Desmin, BerEP4, CEA, Beta-Catenin, Synaptophysin, TTF-1, CD34 and S-100. Because the morphology is suggestive of synovial sarcoma, the specimen was sent for genetic testing for t(x,18) which was negative. The official report is included below.

Overall, although the morphology is slightly unusual for mesothelioma, and the loss of keratin staining in a large part of the sarcomatoid tumor is also unusual, positivity for other mesothelial markers (calretinin, WT-1, CAIX, and D2-40) supports this diagnosis. Dr. [] has reviewed the case and concurs with the diagnosis.

RECEIVED FROM xxxxxxxxxxxxxxxx xx/xx/

Pleural peel (xxxxxx, xx/xx/ : No or fusion transcript was detected by RT-DNA amplification.

[], M.D.

Procedure Notes:

Molecular Oncology Number: xxxxxx

Specimen Type: Paraffin embedded unstained slides

RT-DNA amplification for Synovial Sarcoma Fusion Transcript

Assay No: xxxxxx

[page 3 of 4]
ORIGINAL REPORT ON FILE IN SURGICAL PATHOLOGY LABORATORY

xxxx

[] M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] MD, PhD

Electronically Signed Out by [] M.D.

Clinical History:

The patient is a -year-old male with malignant spindle cell neoplasm undergoing pleurectomy, decortication, thoracotomy.

Specimens Received:

A: Right chest wall mass

B: R4 lymph node

C: Number 7

D: Pleural peel

Gross Description:

The specimens are received in four containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right chest wall mass". Received fresh and placed in formalin are 4 soft, rubbery, pink-tan tissue fragments measuring 6.0 x 4.8 x 1.6 cm in aggregate, all of which are serially sectioned and representative section submitted as A1 and A2.

B. The second container is additionally identified as, "R4 lymph node". Received fresh and placed in formalin are 2 soft, yellow-tan tissue fragments measuring 4.5 x 1.2 x 0.8 cm and 1.0 x 1.1 x 0.3 cm which are submitted entirely as follows:

B1-B2: One lymph node candidate, bisected, a one half in each cassette

B3: 2 lymph node candidates

C. The third container is additionally identified as, "#7". Received fresh and placed in formalin are multiple soft, rubbery, pink-tan tissue fragments measuring 2.7 x 4.5 x 0.9 cm in aggregate are submitted entirely as follows:

C1: 2 lymph node candidates, bisected

C2: 5 lymph node candidates

C3: 2 lymph node candidates

C4: 5 lymph node candidates

C5: One lymph node candidate, bisected

C6: One lymph node candidate, bisected

D. The fourth container is additionally identified as, "right pleural".

[page 4 of 4]
Received fresh and placed in formalin is a right pleurectomy specimen with a volumetric measurement of 1250 ml. The specimen is received in 2 large portions, a tumor mass and a pleura with multiple thickened areas, with a combined weight of 1105 gm. The tumor mass measures 18.5 x 18.5 x 11.0 cm and the thickened pleura measures 18.0 x 17.0 x 0.9 cm. According to the requisition form, there is a stitch designating the diaphragm, which is identified. The diaphragm measures 16.0 x 11.0 cm and the abdominal surface of the diaphragm is inked blue. At this site, the tissue is rubbery, firm, tan. There is no adherent pericardium. The parietal pleura is thickened, white-tan, nodular, rubbery, fibrotic and is intact surrounding the lung. 90% of parietal pleura received is encased in firm, yellow-gray tumor nodules measuring up to 5.8 x 2.1 cm located predominantly along the anterolateral aspect of the chest. The visceral and parietal pleura are thickened up to 0.7 cm and fused. The diaphragmatic margin is actively involved with tumor and tumor is within 0.2 cm of the inked resection margin.

Block Summary:

D1-D5: diaphragm margin

D6-D7: sections of largest pleura tumor deposits

D8-D12: tumor abutting visceral surface/side

D13-D17: Tumor abutting the chest wall

D18-D21: sections from thickened pleura

D22: thickened piece of adipose tissue

xxx

[], MD, PhD

Source: NCI Genomic Data Commons file 75371c39-83ff-4793-8bbe-cf533799ae46 (TCGA-3U-A98F.44D82403-023E-455C-94DC-2D5FFB25D3D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).